Somatic mutation profile of tumor specimen C3L-07147-01 (aliquot CPT0461500006) from CPTAC case C3L-07147, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.9 years (28,102 days).
Specimen C3L-07147-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04be157c-045e-4f45-a252-de04aee7cc69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07147-71 (Blood Derived Normal), aliquot CPT0460210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c2198b-3674-4b43-8341-348decf17a99

The open-access MAF lists 254 somatic variants for this specimen: 181 protein-altering or splice-affecting, 60 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 60, Nonsense Mutation 10, Intron 9, Frame Shift Del 8, Splice Region 3, Frame Shift Ins 3, Splice Site 2, 5'UTR 2, In Frame Del 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSB | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs758641798, COSV53718888; called by muse, mutect2, varscan2
- ARSI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs149628658; called by muse, mutect2, varscan2
- ATG9B | c.1602C>A p.F534L | Missense Mutation (SNP) | VAF 126/435 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1307702070, COSV99872164; called by muse, mutect2, varscan2
- ATP1A2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 116/874 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs796052278, COSV63404484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.1075G>A p.A359T (on ENST00000352432; = p.A325T on NM_001683.5) | Missense Mutation (SNP) | VAF 147/1002 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs766822562; called by muse, mutect2, varscan2
- ATP2B3 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54864748; called by muse, mutect2
- CCT8L2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 31/483 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs1263893382, COSV63463986; called by muse, mutect2
- CD1A | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 74/341 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779636773, COSV56864039; called by muse, mutect2, varscan2
- CDH23 | c.4038C>G p.I1346M | Missense Mutation (SNP) | VAF 39/495 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1197460691; called by muse, mutect2
- CELSR2 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs757463771; called by muse, mutect2, varscan2
- CFAP53 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 19/204 reads (9%) | catalogued as COSV68351989; called by muse, mutect2
- COL21A1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1338004950, COSV104391750; called by muse, mutect2, varscan2
- COL4A5 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 95/444 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs137930367; called by muse, mutect2, varscan2
- CUBN | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1324098366; called by mutect2, varscan2
- DACT3 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 37/465 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.141); catalogued as rs780113189; called by muse, mutect2
- DCAF12L1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 184/598 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64421788; called by muse, mutect2, varscan2
- DGCR8 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1460329898; called by muse, mutect2, varscan2
- DHRS3 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV66107573; called by muse, mutect2
- DNAH7 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1312070225; called by muse, mutect2
- DNAI1 | c.1004T>A p.V335D | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54285398; called by muse, mutect2, varscan2
- DSPP | c.2372G>C p.S791T | Missense Mutation (SNP) | VAF 35/632 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as rs1355589985; called by muse, mutect2
- EGFLAM | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 242/559 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100380735; called by muse, mutect2, varscan2
- EIF4E2 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 26/318 reads (8%) | catalogued as rs370171571; called by muse, mutect2
- EPHB4 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 113/980 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772917108; called by muse, mutect2, varscan2
- ERP27 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 69/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758134274, COSV56762781; called by muse, mutect2, varscan2
- FAM111B | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1181155864; called by muse, mutect2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- FSIP2 | c.4798C>T p.H1600Y | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1448134868; called by muse, mutect2
- FUT9 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 76/318 reads (24%) | catalogued as COSV100134675; called by muse, mutect2, varscan2
- GABRA6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.248); catalogued as COSV50890852; called by muse, mutect2, varscan2
- GRID1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs201182031, COSV60024125; ClinVar: benign; called by muse, mutect2, varscan2
- H1-7 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 97/564 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.574); catalogued as COSV58602374; called by muse, mutect2, varscan2
- HCN1 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV57536576; called by muse, mutect2
- HECA | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 18/578 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV62768233; called by muse, mutect2
- IGFBP4 | c.507G>A p.V169= | Splice Region (SNP) | VAF 54/234 reads (23%) | catalogued as rs749909391; called by muse, mutect2, varscan2
- IGKV1-8 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 38/511 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs1399140045; called by muse, mutect2
- ITIH2 | c.452C>A p.T151K | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV64431976; called by muse, mutect2, varscan2
- KCNA3 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV63901287; called by muse, mutect2, varscan2
- KCNS3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 288/498 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs371345847, COSV100411601; called by muse, mutect2, varscan2
- KIF19 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs754064985, COSV63429341; called by muse, mutect2
- LRP1 | c.10285G>A p.G3429S | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.999); catalogued as rs138926827; called by muse, mutect2, varscan2
- MAP3K10 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs910895614; called by muse, mutect2
- MSR1 | c.634A>T p.I212F | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV50537801; called by muse, mutect2, varscan2
- MTFR2 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100886688; called by muse, mutect2, varscan2
- MUC3A | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 77/811 reads (9%) | SIFT tolerated, low confidence (0.17); catalogued as rs781659697, COSV60212876; called by muse, mutect2
- MYCBP2 | c.4961C>T p.T1654I (on ENST00000357337; = p.T1692I on NM_015057.5) | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV62037036; called by muse, mutect2, varscan2
- MYH14 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs571071269, COSV51817554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5L | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 76/559 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs766675424; called by muse, mutect2, varscan2
- NMT2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781776823, COSV65382309; called by muse, mutect2, varscan2
- NPHS1 | c.2205C>A p.D735E | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as rs1371088115; called by muse, mutect2, varscan2
- NSUN7 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs200936229; called by muse, mutect2, varscan2
- NYNRIN | c.4792G>A p.E1598K | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as rs749999800, COSV101230566; called by muse, mutect2, varscan2
- OR1B1 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs981107347, COSV100506539, COSV59171477; called by muse, mutect2, varscan2
- PAX5 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63905912, COSV63907429; called by muse, mutect2, varscan2
- PCDH18 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV61267216; called by muse, mutect2
- PCDH8 | c.1806G>T p.Q602H | Missense Mutation (SNP) | VAF 110/627 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58814136; called by muse, mutect2, varscan2
- PCDHA3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV65369243; called by muse, mutect2, varscan2
- PCDHB13 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV53396377; called by muse, mutect2, varscan2
- PEAK1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56930084, COSV56936742; called by muse, mutect2
- PHF2 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63681671; called by mutect2, varscan2
- PJA1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1395025999; called by muse, mutect2
- PKHD1 | c.9320G>A p.R3107Q | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs751750213, COSV61895012; called by muse, mutect2, varscan2
- PLBD2 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 144/413 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs768155577; called by muse, mutect2, varscan2
- POM121L12 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs778713354, COSV101374810; called by mutect2, varscan2
- PREX1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs765081103, COSV64250064, COSV64254867; called by muse, mutect2, varscan2
- PTPRN2 | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 107/399 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs868406760; called by muse, mutect2, varscan2
- RESF1 | c.2965_2968del p.N989Efs*4 | Frame Shift Del (DEL) | VAF 198/510 reads (39%) | catalogued as rs745625486; called by pindel, varscan2
- RFC1 | c.2206G>T p.E736* (on ENST00000381897 / NM_001363496.2; = p.E735* on NM_002913.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | catalogued as COSV62898738; called by muse, mutect2, varscan2
- RGPD3 | c.4177G>A p.V1393I | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); catalogued as rs750285003; called by muse, mutect2, varscan2
- RIMKLB | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 301/650 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs746088886, COSV55240453; called by muse, mutect2, varscan2
- SETD2 | c.3490C>G p.Q1164E | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as COSV57453918; called by muse, mutect2
- SIGLEC1 | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 42/458 reads (9%) | catalogued as rs200143991; called by muse, mutect2
- SNRPN | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs761495657, COSV100578050; called by muse, mutect2
- STS | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54265356; called by muse, varscan2
- TOPAZ1 | c.2103A>C p.E701D | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.12); catalogued as COSV100554627; called by muse, mutect2, varscan2
- TPO | c.1649A>T p.Q550L | Missense Mutation (SNP) | VAF 32/628 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as COSV61099206; called by muse, mutect2
- TRPV5 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 85/299 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs544283001, COSV54683375; called by muse, mutect2, varscan2
- UBE3A | c.1618C>T p.L540= | Splice Region (SNP) | VAF 46/185 reads (25%) | catalogued as rs748350055; called by muse, mutect2, varscan2
- UNC80 | c.5048C>T p.S1683L | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1172295484; called by muse, mutect2, varscan2
- UTF1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 155/518 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV58678175; called by muse, mutect2, varscan2
- ZC3H12A | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 88/469 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as rs765523307; called by muse, mutect2, varscan2
- ZFC3H1 | c.5092G>A p.A1698T | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs1251374678; called by muse, mutect2, varscan2
- ZNF217 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs759892207; called by muse, varscan2
- ABCD2 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AC092835.1 | c.1192T>G p.F398V | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS13 | c.3364G>T p.V1122L | Missense Mutation (SNP) | VAF 122/496 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ADGRG4 | c.2687dup p.L897Ifs*3 | Frame Shift Ins (INS) | VAF 101/492 reads (21%) | called by mutect2, pindel, varscan2
- AFP | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by mutect2, varscan2
- ANP32D | c.280A>C p.N94H | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 88/437 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB6 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.526); called by muse, mutect2
- BRD3 | c.1193del p.V398Gfs*13 | Frame Shift Del (DEL) | VAF 71/295 reads (24%) | called by mutect2, pindel, varscan2
- C5 | c.2043G>T p.K681N | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, varscan2
- CACNA1A | c.2032A>G p.I678V | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CADM3 | c.545A>G p.D182G (on ENST00000368125 / NM_001127173.3; = p.D216G on NM_021189.5) | Missense Mutation (SNP) | VAF 76/489 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CCDC65 | c.1153_1154del p.E385Rfs*4 | Frame Shift Del (DEL) | VAF 70/397 reads (18%) | called by mutect2, pindel, varscan2
- CD47 | c.377T>A p.I126N | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CGRRF1 | c.779_780del p.S260* | Frame Shift Del (DEL) | VAF 56/288 reads (19%) | called by pindel, varscan2
- CLHC1 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTN3 | c.1859A>G p.E620G | Missense Mutation (SNP) | VAF 106/572 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CNTN4 | c.2567T>C p.V856A | Missense Mutation (SNP) | VAF 70/937 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2
- CNTN5 | c.1576A>C p.K526Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2
- CNTNAP5 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- COL5A1 | c.3818G>A p.G1273D | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRB2 | c.2998G>C p.G1000R | Missense Mutation (SNP) | VAF 294/577 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRTC3 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 23/575 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUBN | c.2154A>C p.E718D | Missense Mutation (SNP) | VAF 68/380 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- CUL4B | c.2533G>C p.D845H | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDHD1 | c.499A>C p.T167P (on ENST00000323669; = p.T364P on NM_030637.3) | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); called by muse, mutect2
- DICER1 | c.346C>G p.H116D | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.927); called by muse, mutect2
- EHMT1 | c.2444A>G p.E815G | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- EID3 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- ENO4 | c.1444G>T p.E482* (on ENST00000622726; = p.E479* on NM_001242699.2) | Nonsense Mutation (SNP) | VAF 92/506 reads (18%) | called by muse, mutect2, varscan2
- ENO4 | c.1445A>G p.E482G (on ENST00000622726; = p.E479G on NM_001242699.2) | Missense Mutation (SNP) | VAF 94/508 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- EPS8 | c.1681C>G p.L561V | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FCRL3 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FLII | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2
- FMN2 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.012); called by muse, mutect2
- FXR1 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDF15 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL2 | c.63_64dup p.P22Lfs*24 | Frame Shift Ins (INS) | VAF 56/289 reads (19%) | called by mutect2, pindel, varscan2
- GRM1 | c.3191C>G p.S1064C | Missense Mutation (SNP) | VAF 106/497 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- H2BC8 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- HLTF | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- IL13RA2 | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IRGQ | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCND1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHNYN | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA1217 | c.1903_1944del p.P635_E648del | In Frame Del (DEL) | VAF 44/498 reads (9%) | called by mutect2, pindel
- LHX6 | c.545G>T p.R182L (on ENST00000373755 / NM_001242334.2; = p.R211L on NM_014368.5) | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAGEB4 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 128/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- MALRD1 | c.3139C>A p.P1047T | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by mutect2, varscan2
- MESP2 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 352/596 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MGAM2 | c.2002T>G p.L668V | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYLIP | c.88-1G>A p.X30_splice | Splice Site (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- NACC2 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2
- NACC2 | c.1365C>G p.I455M | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NEURL4 | c.3201C>G p.N1067K | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NPY1R | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- NUP210 | c.5617G>T p.A1873S | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2I1P | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 17/527 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- OR5D3P | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PABPC4 | c.1248T>G p.A416= | Splice Region (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- PDE3A | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 219/568 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PDE3A | c.979T>A p.W327R | Missense Mutation (SNP) | VAF 116/601 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHF3 | c.1461del p.K487Nfs*8 | Frame Shift Del (DEL) | VAF 90/353 reads (25%) | called by mutect2, pindel, varscan2
- PLEKHH3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHM3 | c.1155C>A p.S385R | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- PLXNB2 | c.2386A>G p.T796A | Missense Mutation (SNP) | VAF 97/476 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG3 | c.594del p.N198Kfs*26 | Frame Shift Del (DEL) | VAF 75/312 reads (24%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PUS7 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RILP | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 38/615 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2
- SBK2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 249/440 reads (57%) | called by muse, mutect2, varscan2
- SCFD1 | c.1491-1G>T p.X497_splice | Splice Site (SNP) | VAF 19/243 reads (8%) | called by muse, mutect2
- SCYGR3 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 29/724 reads (4%) | called by muse, mutect2
- SGO2 | c.1100dup p.L367Ffs*4 | Frame Shift Ins (INS) | VAF 74/374 reads (20%) | called by mutect2, pindel, varscan2
- SLC2A5 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 116/505 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC34A3 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 46/344 reads (13%) | called by muse, mutect2, varscan2
- SLC49A4 | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- SLC6A8 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STX1A | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, varscan2
- SYCE1 | c.436G>T p.E146* (on ENST00000343131 / NM_001143764.3; = p.E110* on NM_130784.3) | Nonsense Mutation (SNP) | VAF 25/475 reads (5%) | called by muse, mutect2
- SYCP1 | c.1568T>G p.L523R | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYNE2 | c.7843C>T p.Q2615* | Nonsense Mutation (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- TAMM41 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 77/920 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- TAMM41 | c.375G>T p.W125C | Missense Mutation (SNP) | VAF 75/992 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM3 | c.4890del p.F1630Lfs*9 | Frame Shift Del (DEL) | VAF 79/195 reads (41%) | called by mutect2, pindel, varscan2
- THAP4 | c.1492G>C p.V498L | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TNXB | c.9223G>T p.A3075S (on ENST00000647633; = p.A2828S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- TPO | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 319/567 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- TPP2 | c.3213A>C p.K1071N | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TTC8 | c.175G>A p.V59I (on ENST00000338104 / NM_001288781.1; = p.V69I on NM_144596.4) | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- USP15 | c.2668_2670del p.G890del (on ENST00000280377 / NM_001351159.2; = p.G861del on NM_006313.3 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 26/204 reads (13%) | called by pindel, varscan2
- VMP1 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2
- ZBTB40 | c.1629G>T p.K543N | Missense Mutation (SNP) | VAF 93/544 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZFC3H1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 137/423 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZMYND8 | c.2539C>G p.Q847E | Missense Mutation (SNP) | VAF 78/588 reads (13%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.021); called by mutect2, varscan2
- ZNF2 | c.725A>G p.Y242C (on ENST00000611147 / NM_001291605.2; = p.Y229C on NM_021088.4) | Missense Mutation (SNP) | VAF 111/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF250 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/511 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2
- ZYG11B | c.2172del p.K724Nfs*20 | Frame Shift Del (DEL) | VAF 131/511 reads (26%) | called by mutect2, pindel, varscan2
- ABCB4 | c.762C>T p.A254= | Silent (SNP) | VAF 185/506 reads (37%) | catalogued as rs747537137; called by muse, mutect2, varscan2
- ABCC9 | c.600G>A p.Q200= | Silent (SNP) | VAF 12/370 reads (3%) | called by muse, mutect2
- ADAR | c.2697C>T p.L899= | Silent (SNP) | VAF 21/736 reads (3%) | called by muse, mutect2
- ARHGEF18 | c.1752G>T p.L584= (on ENST00000359920 / NM_001130955.2; = p.L480= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/316 reads (20%) | called by muse, mutect2, varscan2
- ASXL3 | c.2832G>A p.E944= | Silent (SNP) | VAF 72/242 reads (30%) | called by muse, mutect2, varscan2
- BCOR | c.180G>A p.T60= | Silent (SNP) | VAF 84/328 reads (26%) | catalogued as rs918158091; called by muse, mutect2, varscan2
- BEND5 | c.837G>A p.S279= | Silent (SNP) | VAF 107/379 reads (28%) | catalogued as rs34838490; called by muse, mutect2, varscan2
- CATSPERE | c.2478C>A p.V826= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV100835266; called by muse, mutect2, varscan2
- CDH22 | c.339C>T p.D113= | Silent (SNP) | VAF 187/490 reads (38%) | catalogued as rs774411837, COSV64837003, COSV64839481; called by muse, mutect2, varscan2
- CHST3 | c.705G>A p.T235= | Silent (SNP) | VAF 115/391 reads (29%) | called by muse, mutect2, varscan2
- CYP1B1 | c.870C>T p.R290= | Silent (SNP) | VAF 97/407 reads (24%) | catalogued as COSV53190571; called by muse, mutect2, varscan2
- DHRS9 | c.846C>T p.A282= | Silent (SNP) | VAF 119/500 reads (24%) | catalogued as rs374313197; called by muse, mutect2, varscan2
- EHBP1 | c.39A>G p.K13= | Silent (SNP) | VAF 12/359 reads (3%) | catalogued as COSV50416677; called by muse, mutect2
- FAM200B | c.1521G>A p.E507= | Silent (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- FAT3 | c.8550T>G p.T2850= | Silent (SNP) | VAF 10/307 reads (3%) | called by muse, mutect2
- FOXD3 | c.183G>T p.V61= | Silent (SNP) | VAF 107/419 reads (26%) | called by muse, mutect2, varscan2
- GPR179 | c.5703T>C p.S1901= (on ENST00000621958; = p.S1900= on NM_001004334.4) | Silent (SNP) | VAF 82/440 reads (19%) | called by muse, mutect2, varscan2
- GRIK3 | c.1458G>A p.V486= | Silent (SNP) | VAF 105/465 reads (23%) | called by muse, mutect2, varscan2
- GRM1 | c.1089G>A p.T363= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as rs753266032, COSV51107983; called by muse, mutect2
- GYS2 | c.1704T>A p.T568= | Silent (SNP) | VAF 82/632 reads (13%) | called by muse, mutect2, varscan2
- HHIP | c.517A>C p.R173= | Silent (SNP) | VAF 65/318 reads (20%) | called by muse, mutect2, varscan2
- IGSF9B | c.2373A>T p.R791= | Silent (SNP) | VAF 81/222 reads (36%) | called by muse, mutect2, varscan2
- JAZF1 | c.255G>A p.S85= | Silent (SNP) | VAF 28/472 reads (6%) | catalogued as rs1169331149; called by muse, mutect2
- KBTBD8 | c.315G>A p.L105= | Silent (SNP) | VAF 42/588 reads (7%) | called by muse, mutect2
- KCP | c.4368C>T p.C1456= (on ENST00000620378; = p.C1580= on NM_001366122.1) | Silent (SNP) | VAF 32/628 reads (5%) | catalogued as rs538963633; called by muse, mutect2
- KLF2 | c.678C>T p.A226= | Silent (SNP) | VAF 89/343 reads (26%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1392C>T p.L464= (on ENST00000395676; = p.L1105= on NM_138433.5) | Silent (SNP) | VAF 115/715 reads (16%) | called by muse, mutect2, varscan2
- KLHL17 | c.1782C>T p.I594= | Silent (SNP) | VAF 48/452 reads (11%) | catalogued as rs750113112, COSV58530873; called by muse, mutect2, varscan2
- KMT2B | c.3210C>T p.L1070= | Silent (SNP) | VAF 22/903 reads (2%) | catalogued as COSV55866399; called by muse, mutect2
- LHX5 | c.117C>T p.L39= | Silent (SNP) | VAF 29/580 reads (5%) | called by muse, mutect2
- LMOD2 | c.822C>T p.N274= | Silent (SNP) | VAF 221/387 reads (57%) | catalogued as rs764088293, COSV71755484; called by muse, mutect2, varscan2
- MNDA | c.351C>T p.T117= | Silent (SNP) | VAF 77/674 reads (11%) | catalogued as rs375325126; called by muse, mutect2, varscan2
- MOCS3 | c.429C>T p.A143= | Silent (SNP) | VAF 124/607 reads (20%) | called by muse, mutect2, varscan2
- MXRA5 | c.6435C>T p.N2145= | Silent (SNP) | VAF 116/500 reads (23%) | catalogued as rs749463842, COSV54227648, COSV54243431; called by muse, mutect2, varscan2
- OBSCN | c.366C>T p.R122= | Silent (SNP) | VAF 33/560 reads (6%) | called by muse, mutect2
- OR6Y1 | c.699C>T p.I233= | Silent (SNP) | VAF 22/743 reads (3%) | called by muse, mutect2
- P3H3 | c.1632C>T p.T544= | Silent (SNP) | VAF 24/768 reads (3%) | called by muse, mutect2
- PCDHA2 | c.1974G>A p.A658= | Silent (SNP) | VAF 125/284 reads (44%) | called by muse, mutect2, varscan2
- PCLO | c.13782A>G p.S4594= | Silent (SNP) | VAF 58/277 reads (21%) | called by muse, varscan2
- PDZD2 | c.1746C>T p.S582= | Silent (SNP) | VAF 81/462 reads (18%) | catalogued as rs778124527, COSV99226518; called by muse, mutect2, varscan2
- PDZD2 | c.4506G>A p.S1502= | Silent (SNP) | VAF 344/603 reads (57%) | catalogued as rs763224127; called by muse, mutect2, varscan2
- PIEZO2 | c.459A>G p.A153= | Silent (SNP) | VAF 77/215 reads (36%) | called by muse, mutect2, varscan2
- PLA2G3 | c.1269A>C p.T423= | Silent (SNP) | VAF 22/357 reads (6%) | called by muse, mutect2
- PRMT9 | c.27C>G p.R9= | Silent (SNP) | VAF 38/464 reads (8%) | called by muse, mutect2
- PRRC2B | c.5121G>A p.A1707= | Silent (SNP) | VAF 76/515 reads (15%) | catalogued as rs371286973; called by muse, mutect2, varscan2
- RAD51 | c.351T>C p.I117= | Silent (SNP) | VAF 11/274 reads (4%) | called by muse, mutect2
- SACS | c.11580A>T p.I3860= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- SEMA4D | c.1956C>T p.P652= | Silent (SNP) | VAF 90/505 reads (18%) | catalogued as rs781459597; called by muse, mutect2, varscan2
- SEZ6L2 | c.2073T>C p.S691= (on ENST00000308713 / NM_001114099.3; = p.S621= on NM_012410.4) | Silent (SNP) | VAF 118/364 reads (32%) | called by muse, mutect2, varscan2
- SLAMF6 | c.891C>A p.I297= (on ENST00000368057 / NM_001184714.2; = p.I296= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- SPEM3 | c.345G>A p.T115= | Silent (SNP) | VAF 12/304 reads (4%) | catalogued as rs1454400032; called by muse, mutect2
- SPEN | c.69C>T p.I23= | Silent (SNP) | VAF 79/450 reads (18%) | catalogued as COSV100402931; called by muse, mutect2, varscan2
- TBC1D31 | c.1008G>A p.Q336= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs528449440; called by muse, mutect2, varscan2
- TEX13C | c.408G>T p.L136= | Silent (SNP) | VAF 17/489 reads (3%) | called by muse, mutect2
- UBASH3A | c.942C>T p.S314= | Silent (SNP) | VAF 101/313 reads (32%) | catalogued as rs147873921, COSV52315986; called by muse, mutect2, varscan2
- UBE3B | c.3141G>A p.K1047= | Silent (SNP) | VAF 46/653 reads (7%) | called by muse, mutect2
- USP20 | c.660C>G p.V220= | Silent (SNP) | VAF 56/310 reads (18%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1083C>T p.S361= | Silent (SNP) | VAF 108/421 reads (26%) | catalogued as rs768822061; called by muse, mutect2, varscan2
- ZNF536 | c.2145G>A p.P715= | Silent (SNP) | VAF 56/750 reads (7%) | catalogued as rs1245802145, COSV100835268, COSV62826176; called by muse, mutect2
- ZNF566 | c.756G>A p.E252= | Silent (SNP) | VAF 21/423 reads (5%) | called by muse, mutect2
- AP003393.1 | n.514+733T>C | Intron (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- ARHGDIA | c.*479C>G | 3'UTR (SNP) | VAF 106/406 reads (26%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+34G>T | Intron (SNP) | VAF 60/253 reads (24%) | catalogued as COSV52882372; called by muse, mutect2, varscan2
- EXD1 | c.29-2687A>G | Intron (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
- GRK4 | c.52+1134G>A | Intron (SNP) | VAF 137/274 reads (50%) | catalogued as rs868168114, COSV100054626; called by muse, mutect2, varscan2
- HOXB3 | c.-269G>A | 5'UTR (SNP) | VAF 76/318 reads (24%) | catalogued as rs1333549721; called by muse, mutect2, varscan2
- IAPP | c.80+285C>T | Intron (SNP) | VAF 147/429 reads (34%) | catalogued as rs984441147, COSV53714752; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-35988T>C | Intron (SNP) | VAF 24/223 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+10193G>A | Intron (SNP) | VAF 49/233 reads (21%) | catalogued as rs1225065970; called by muse, mutect2, varscan2
- PFKFB2 | chr1:207078997 C>T | 3'Flank (SNP) | VAF 48/256 reads (19%) | catalogued as rs772479545; called by muse, mutect2, varscan2
- REV3L | c.-225C>G | 5'UTR (SNP) | VAF 95/366 reads (26%) | catalogued as COSV62614398; called by muse, mutect2, varscan2
- UMAD1 | c.82+2741C>G | Intron (SNP) | VAF 62/364 reads (17%) | called by mutect2, varscan2
- ZNF160 | c.271+662G>T | Intron (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
